Surgical pathology report (de-identified scan), TCGA case TCGA-A7-A0CJ, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Christiana Healthcare, specimen TCGA-A7-A0CJ-01A (Primary Tumor).

[page 1 of 2]
1CD-0-3

Carcinoma, infiltrating duct, Nos 8500/3

Site: breast, Nos C50.9 lw 9/3/4

SPECIMEN

- A. Left axillary sentinel lymph node
- B. Left breast biopsy

CLINICAL NOTES

CLINICAL HISTORY: A -year-old white female with left breast cancer.

FROZEN SECTION DIAGNOSIS

AFS: Left axillary sentinel node, excision - One lymph node with no metastasis identified.

GROSS DESCRIPTION

A. Container A is labeled with the patient's name, medical record number and "left axillary sentinel node". The specimen consists of a single partially fatty replaced lymph node measuring 1.3 x 1 x 0.6 cm. AFS, bisected.

B. Container B is labeled with the patient's name, medical record number and "left breast biopsy, long anterior, short

superior." The specimen consists of a single piece of fibrous adipose tissue oriented by two sutures and measuring 6.5 cm in medial to lateral, 3.5 cm from superior to inferior and 3 cm from anterior to posterior. The specimen margins are inked as follows: Blue -- anterior; black -- posterior; yellow -- lateral; orange -- medial; red -- superior; green -- inferior. The specimen is serially sectioned. On cut section, there is a firm tan fibrotic-appearing tumor mass measuring 2.2 x 1.5 x 1.8 cm. The mass appears to extend to the posterior margin of resection. A portion is submitted for tissue procurement. The remainder of the tissue is submitted in blocks 1-15.

MICROSCOPIC DESCRIPTION

A. Sections of the left axillary sentinel lymph node demonstrate 1 lymph node with no evidence of metastasis. The lymph node was examined and multilevel sectioning with H&E stain

as well as immunohistochemistry for pankeratin.

B. The following template applies to the left breast biopsy:

Invasive Carcinoma: Present.

Histologic type: Infiltrating ductal carcinoma

Histologic grade:

Overall grade: 3

Architectural score: 3

Nuclear score: 3

Mitotic score: 2

[page 2 of 2]
Greatest dimension (pT): 2.2 cm. (pT2)
Specimen margins: Positive.
Invasive carcinoma extended to the green ink involving the
inferior margin.
Vessel invasion: Not identified.
Calcification: Present

Ductal carcinoma in situ: Present
Histologic pattern: Solid and cribriform
Nuclear grade: 2-3
Central necrosis: Focally present
%DCIS of total tumor: 25%
Extensive intraductal component (present/absent): Present
Specimen margins: Close. In situ carcinoma is less than 1 mm
from the anterior, posterior, medial and inferior margins.
Calcification: Present

Description of non-tumorous breast: Proliferative changes.
Comments: None.

MICROSCOPIC DESCRIPTION

Prognostic markers: Previously performed.

4x2, 20

DIAGNOSIS

- A. Left axillary sentinel lymph node, resection:
No evidence of metastasis in one lymph node (0/1).
- B. Left breast, excisional biopsy:
Infiltrating ductal carcinoma, grade 3, 2.2 cm. extending to
the inferior margin.
Extensive ductal carcinoma in situ, solid and cribriforming
subtypes, nuclear grade 2-3, less than 1 mm from multiple
margins.

M.D, (Electronic Signature)

--- End Of Report ---

Source: NCI Genomic Data Commons file 00b5b8bc-4d91-4e8c-925b-1c6c91430b13 (TCGA-A7-A0CJ.019F390D-7479-4CDC-8C82-45A27910E782.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).